Somatic mutation profile of tumor specimen TCGA-2G-AAM4-01A (aliquot TCGA-2G-AAM4-01A-11D-A435-10) from TCGA case TCGA-2G-AAM4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAM4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f27c7ad7-140e-4961-a208-c4775623da5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAM4-10A (Blood Derived Normal), aliquot TCGA-2G-AAM4-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f9792a-d219-4923-a76a-7668bdb53c33

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP36 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52266407, COSV52267326; called by muse, mutect2, varscan2
- CRACR2B | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as rs1254500666; called by muse, mutect2, varscan2
- ABCC6 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DCAF12 | c.1179A>C p.K393N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2
- DPP3 | c.2075del p.S692* | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel*, varscan2
- IL21R | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- JARID2 | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PPP2R5D | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCOF1 | c.1469C>T p.A490V (on ENST00000377797 / NM_001135243.1; = p.A413V on NM_000356.4) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TELO2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TRPM5 | c.1554G>A p.W518* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- TYSND1 | c.1098del p.V367* | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- ARID4B | c.2976C>T p.V992= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1558175468; called by muse, mutect2
- NBR1 | c.1170C>T p.T390= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- PHC2 | c.900G>A p.V300= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- HBS1L | c.430+1983A>G | Intron (SNP) | VAF 29/83 reads (35%) | catalogued as rs1398685756; called by muse, mutect2, varscan2
- IFI44L | c.*9G>T | 3'UTR (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- PTPMT1 | c.175-23G>T | Intron (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
